CCDI case PBBUSK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/91774c49-7436-4add-af64-a39feeb1e5df

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.5 years (184 days).

Biospecimens (3 samples)
- Sample 0DJBLN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJC30: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJC36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
